Somatic mutation profile of tumor specimen 0DP47P from CCDI case PBCDFM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroepithelioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,637 days).
Specimen 0DP47P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17dad969-5650-4e1b-9b9d-0e67dc8a1a6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP46Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/930019a0-b793-4a14-b0a9-99e60bf6fa55

The open-access MAF lists 110 somatic variants for this specimen: 67 protein-altering or splice-affecting, 23 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 23, Intron 14, Nonsense Mutation 4, 3'UTR 3, 5'UTR 2, In Frame Del 2, Splice Region 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.82A>C p.T28P | Missense Mutation (SNP) | VAF 118/2656 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768399283; called by muse, mutect2
- BDP1 | c.4889A>G p.E1630G | Missense Mutation (SNP) | VAF 60/1260 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as rs1409116050; called by muse, mutect2
- CAPN15 | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 231/642 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780804268, COSV99562132; called by muse, mutect2, varscan2
- COL12A1 | c.5831A>G p.N1944S | Missense Mutation (SNP) | VAF 111/1518 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs769479852; called by muse, mutect2
- COL6A3 | c.8231C>T p.T2744M | Missense Mutation (SNP) | VAF 98/1620 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373680762; called by muse, mutect2
- DDI1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 341/560 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs865913257; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.376G>C p.G126R | Missense Mutation (SNP) | VAF 126/610 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375880079; called by muse, mutect2, varscan2
- LAIR1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 60/926 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs758156418; called by muse, mutect2
- PAEP | c.298T>G p.F100V | Missense Mutation (SNP) | VAF 88/1362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52985120; called by muse, mutect2
- PDE3B | c.1078C>G p.R360G | Missense Mutation (SNP) | VAF 76/1110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56390696; called by muse, mutect2
- PHACTR2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 521/1930 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs566532922, COSV59855684; called by muse, mutect2, varscan2
- PRX | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 82/1132 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs757322355; called by muse, mutect2
- PTPRK | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 30/1156 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as rs1386581406; called by muse, mutect2
- PWWP3B | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 571/1336 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as COSV61799710; called by muse, mutect2, varscan2
- RSPH3 | c.1358G>A p.R453K (on ENST00000252655; = p.R311K on NM_031924.8) | Missense Mutation (SNP) | VAF 43/1115 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1562558148; called by muse, mutect2
- TCF4 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 36/910 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100610054; called by muse, mutect2
- TFAP2D | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 57/1524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50419352; called by muse, mutect2
- UBAP2L | c.2038A>G p.S680G | Missense Mutation (SNP) | VAF 1044/2433 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs770228174; called by muse, mutect2, varscan2
- WDR4 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 34/1132 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV57735613; called by muse, mutect2
- XIRP2 | c.7229A>G p.K2410R (on ENST00000628543; = p.K2585R on NM_152381.6) | Missense Mutation (SNP) | VAF 212/2986 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs767783635; called by muse, mutect2
- ZKSCAN7 | c.1991A>G p.E664G | Missense Mutation (SNP) | VAF 25/720 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs373560883; called by muse, mutect2
- ZNF793 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 105/1581 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71324787; called by muse, mutect2
- ADAM8 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 76/1018 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2
- AHRR | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 86/1008 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- CAP1 | c.1122C>G p.N374K | Missense Mutation (SNP) | VAF 80/1172 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2
- CARS1 | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 34/844 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.361); called by muse, mutect2
- CEP170 | c.3587A>T p.K1196I | Missense Mutation (SNP) | VAF 68/2680 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH5 | c.13394A>G p.N4465S | Missense Mutation (SNP) | VAF 190/1580 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- EML6 | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 91/1430 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- FBXO9 | c.1193A>C p.N398T | Missense Mutation (SNP) | VAF 62/1756 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.423); called by muse, mutect2
- HEPHL1 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 479/1773 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- JADE2 | c.621_629del p.P208_G210del | In Frame Del (DEL) | VAF 335/1322 reads (25%) | called by mutect2, pindel, varscan2
- LCE4A | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 44/1729 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.242); called by muse, mutect2
- LIN28A | c.292A>T p.K98* | Nonsense Mutation (SNP) | VAF 142/1736 reads (8%) | called by muse, mutect2
- LRRC49 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 94/1540 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- LTB4R | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 200/2522 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2
- LY75 | c.1136_1138del p.S379del | In Frame Del (DEL) | VAF 297/1663 reads (18%) | called by mutect2, pindel, varscan2
- MAGI3 | c.2311G>C p.D771H | Missense Mutation (SNP) | VAF 96/2756 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC16 | c.13405T>C p.S4469P | Missense Mutation (SNP) | VAF 56/1890 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.194); called by muse, mutect2
- NCAPH | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 334/1926 reads (17%) | called by muse, mutect2, varscan2
- NEB | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 76/1046 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- NEIL3 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 84/2422 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOMO3 | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 214/1642 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- NOX4 | c.1087A>C p.T363P | Missense Mutation (SNP) | VAF 278/1118 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR6C1 | c.797T>A p.V266E | Missense Mutation (SNP) | VAF 248/1325 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PARP14 | c.3548C>A p.S1183* | Nonsense Mutation (SNP) | VAF 658/1575 reads (42%) | called by muse, mutect2, varscan2
- PIGU | c.779T>G p.F260C | Missense Mutation (SNP) | VAF 103/2464 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); called by muse, mutect2
- PKP3 | c.357G>T p.W119C | Missense Mutation (SNP) | VAF 255/868 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PLD1 | c.911+5A>G | Splice Region (SNP) | VAF 34/1176 reads (3%) | called by muse, mutect2
- PPP1R16A | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 230/1044 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); called by mutect2, varscan2
- PRSS36 | c.273-1G>C p.X91_splice | Splice Site (SNP) | VAF 144/466 reads (31%) | called by muse, mutect2, varscan2
- PSAPL1 | c.590C>G p.A197G | Missense Mutation (SNP) | VAF 187/874 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PSEN1 | c.644G>C p.W215S | Missense Mutation (SNP) | VAF 166/2154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRU | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 209/959 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- RFC1 | c.3243G>C p.K1081N (on ENST00000381897 / NM_001363496.2; = p.K1080N on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/2456 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2
- SLC44A3 | c.1141T>C p.S381P (on ENST00000271227 / NM_001114106.3; = p.S333P on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 372/1814 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SPATA9 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 38/1046 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- STIMATE | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 153/719 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SUSD6 | c.819A>C p.E273D | Missense Mutation (SNP) | VAF 116/1370 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- SVIL | c.1379A>G p.E460G | Missense Mutation (SNP) | VAF 88/1573 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2
- TENM1 | c.2153G>T p.G718V | Missense Mutation (SNP) | VAF 278/675 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM191C | c.916G>C p.V306L | Missense Mutation (SNP) | VAF 326/1287 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TNNI2 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 32/896 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- TTC9 | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 44/653 reads (7%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2
- TUBGCP3 | c.158T>C p.L53S | Missense Mutation (SNP) | VAF 379/1791 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- XPO5 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 325/1115 reads (29%) | called by muse, mutect2, varscan2
- ZNF536 | c.1591A>G p.M531V | Missense Mutation (SNP) | VAF 37/980 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- ATN1 | c.3225G>C p.S1075= | Silent (SNP) | VAF 138/3098 reads (4%) | called by muse, mutect2
- CEP97 | c.2097A>T p.P699= | Silent (SNP) | VAF 509/2557 reads (20%) | called by muse, mutect2, varscan2
- COL4A2 | c.4449C>G p.G1483= | Silent (SNP) | VAF 124/1935 reads (6%) | catalogued as COSV64630029; called by muse, mutect2
- CPAMD8 | c.5055G>T p.T1685= (on ENST00000651564; = p.T1638= on NM_015692.5) | Silent (SNP) | VAF 60/1139 reads (5%) | called by muse, mutect2
- DYNC2H1 | c.1323A>G p.R441= | Silent (SNP) | VAF 66/1775 reads (4%) | called by muse, mutect2
- EIF3B | c.2424T>A p.I808= | Silent (SNP) | VAF 152/791 reads (19%) | catalogued as rs1215974327; called by muse, mutect2, varscan2
- ITGB4 | c.2277A>G p.E759= | Silent (SNP) | VAF 47/1139 reads (4%) | catalogued as rs1190393849; called by muse, mutect2
- KIF13A | c.663C>T p.S221= | Silent (SNP) | VAF 92/2345 reads (4%) | catalogued as COSV52465622; called by muse, mutect2
- KRTAP13-3 | c.510T>C p.G170= | Silent (SNP) | VAF 69/1384 reads (5%) | catalogued as rs750024042; called by muse, mutect2
- MAP4K3 | c.1287A>C p.A429= | Silent (SNP) | VAF 90/2048 reads (4%) | called by muse, mutect2
- MUC22 | c.2139T>G p.S713= | Silent (SNP) | VAF 63/1618 reads (4%) | called by muse, mutect2
- MYBPC3 | c.2766G>T p.G922= | Silent (SNP) | VAF 22/600 reads (4%) | called by muse, mutect2
- OR52N4 | c.54A>G p.G18= | Silent (SNP) | VAF 259/1093 reads (24%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3289T>C p.L1097= (on ENST00000676171; = p.L1056= on NM_004570.5) | Silent (SNP) | VAF 409/1746 reads (23%) | called by muse, mutect2, varscan2
- PKDREJ | c.4476G>A p.V1492= | Silent (SNP) | VAF 48/1767 reads (3%) | called by muse, mutect2
- PPP1R21 | c.450A>G p.E150= | Silent (SNP) | VAF 336/1514 reads (22%) | called by muse, varscan2
- RASGRP2 | c.1158G>C p.P386= | Silent (SNP) | VAF 58/792 reads (7%) | called by muse, mutect2
- SEMA3A | c.1368G>A p.G456= | Silent (SNP) | VAF 142/3786 reads (4%) | called by muse, mutect2
- SMC6 | c.1029A>G p.A343= | Silent (SNP) | VAF 564/2089 reads (27%) | called by muse, mutect2, varscan2
- SUSD1 | c.1375T>C p.L459= | Silent (SNP) | VAF 118/1622 reads (7%) | called by muse, mutect2
- TARBP1 | c.4458A>G p.V1486= | Silent (SNP) | VAF 29/1172 reads (2%) | called by muse, mutect2
- TTN | c.63568C>T p.L21190= (on ENST00000591111; = p.L13766= on NM_003319.4) | Silent (SNP) | VAF 70/2041 reads (3%) | called by muse, mutect2
- VSIG10L | c.369G>A p.S123= | Silent (SNP) | VAF 767/1743 reads (44%) | catalogued as rs1265047745; called by muse, mutect2, varscan2
- CCDC144NL | n.561A>G | RNA (SNP) | VAF 128/3138 reads (4%) | called by muse, mutect2
- DUSP13 | c.*74G>A | 3'UTR (SNP) | VAF 89/1592 reads (6%) | called by muse, mutect2
- EXD3 | c.871-90C>A | Intron (SNP) | VAF 80/284 reads (28%) | called by muse, mutect2, varscan2
- FAM98A | c.-15G>A | 5'UTR (SNP) | VAF 58/893 reads (6%) | called by muse, mutect2
- GZMK | c.213-51T>G | Intron (SNP) | VAF 116/420 reads (28%) | called by muse, mutect2, varscan2
- HGS | c.936+34G>T | Intron (SNP) | VAF 181/750 reads (24%) | called by muse, mutect2, varscan2
- HMCN2 | c.14588-39C>A | Intron (SNP) | VAF 42/1116 reads (4%) | called by muse, mutect2
- IGF2BP3 | c.1321-65G>C | Intron (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- LRRIQ1 | c.5016+22A>G | Intron (SNP) | VAF 82/1936 reads (4%) | catalogued as rs1455954324; called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- MORC1 | c.-69G>A | 5'UTR (SNP) | VAF 26/319 reads (8%) | catalogued as rs527436539, COSV51734103; called by muse, mutect2
- RANBP3L | c.*865C>G | 3'UTR (SNP) | VAF 64/959 reads (7%) | called by muse, mutect2
- RINL | c.51-75C>G | Intron (SNP) | VAF 85/721 reads (12%) | called by muse, mutect2, varscan2
- SLC4A7 | c.*84_*89dup | 3'UTR (INS) | VAF 63/326 reads (19%) | called by mutect2, pindel, varscan2
- TAGAP | c.783+108C>T | Intron (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- TENM2 | c.2780+96G>A | Intron (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- THEM4 | c.287-23G>C | Intron (SNP) | VAF 20/749 reads (3%) | called by muse, mutect2
- TRAF3IP3 | c.1053+48G>A | Intron (SNP) | VAF 34/468 reads (7%) | called by muse, mutect2
- TTN | c.91982-44T>C | Intron (SNP) | VAF 246/1327 reads (19%) | called by muse, mutect2, varscan2
- ZNF806 | n.295-1626T>A | Intron (SNP) | VAF 196/2355 reads (8%) | called by muse, mutect2
